Somatic mutation profile of tumor specimen TCGA-DC-4749-01A (aliquot TCGA-DC-4749-01A-01D-1733-10) from TCGA case TCGA-DC-4749, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 57.7 years (21,092 days).
Specimen TCGA-DC-4749-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6146cd1-829a-47e2-a1b8-0dffa5ad6148.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-4749-10A (Blood Derived Normal), aliquot TCGA-DC-4749-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f42e624e-1544-4205-a74d-d0c2bb20ea25

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Nonsense Mutation 6, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751086, CM014496, COSV52741975; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1717_1719del p.L573del (on ENST00000521381 / NM_181523.3; = p.L303del on NM_181504.4) | In Frame Del (DEL) | VAF 50/99 reads (51%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 64/87 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs778918550, COSV56981665; called by muse, mutect2, varscan2
- ASPHD1 | c.971G>C p.C324S | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100441603; called by muse, mutect2, varscan2
- ATG2A | c.5614G>A p.V1872M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773533718, COSV63475526; called by muse, mutect2, varscan2
- BOD1L1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50007797; called by muse, mutect2, varscan2
- CD300LG | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1384976115, COSV53222976; called by muse, mutect2, varscan2
- CDR2L | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778260267, COSV61500738; called by muse, mutect2, varscan2
- CEP290 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 84/282 reads (30%) | catalogued as rs62640581, CM063893, COSV58349688, COSV58351993; ClinVar: not provided; called by muse, varscan2
- CHRDL1 | c.1246G>T p.G416* (on ENST00000372045; = p.G422* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99487717; called by mutect2, varscan2
- CPZ | c.824G>A p.R275H (on ENST00000360986 / NM_001014447.3; = p.R264H on NM_003652.3) | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749063388, COSV59921949; called by muse, mutect2, varscan2
- CSMD2 | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs750515208, COSV53888438; called by muse, mutect2, varscan2
- CYP4F11 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs770840051, COSV56125963; called by muse, mutect2, varscan2
- DLGAP4 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV59415440; called by muse, mutect2, varscan2
- E2F7 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754335559, COSV59738152; called by muse, mutect2, varscan2
- EPHA5 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1280610278, COSV56635323; called by muse, mutect2, varscan2
- F12 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53690287; called by muse, mutect2, varscan2
- FBXO11 | c.553C>T p.R185C (on ENST00000403359 / NM_001190274.2; = p.R101C on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57017173; called by muse, mutect2, varscan2
- GIMAP4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV55431462; called by muse, mutect2, varscan2
- GLI2 | c.2209C>T p.R737W (on ENST00000361492 / NM_001374353.1; = p.R754W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138932004, COSV58036605; called by muse, mutect2, varscan2
- HECW1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as rs1354837449, COSV67824628; called by muse, mutect2, varscan2
- KCNA4 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs747368709, COSV60251092; called by muse, mutect2, varscan2
- KCNV2 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200353727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1 | c.3943G>T p.D1315Y | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54504558, COSV54512646; called by muse, mutect2, varscan2
- MAG | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs142036180; called by muse, mutect2, varscan2
- MAGEE2 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 25/29 reads (86%) | catalogued as rs746202577, COSV64897231; called by muse, mutect2, varscan2
- MLN | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs746105078, COSV99803045; called by mutect2, varscan2
- MLX | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs759737992, COSV53816424; called by muse, mutect2, varscan2
- MPDZ | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59936932; called by muse, varscan2
- MT1M | c.80C>A p.T27N | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV65835651; called by muse, mutect2, varscan2
- MUC5B | c.11102C>G p.T3701S | Missense Mutation (SNP) | VAF 210/520 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.062); catalogued as rs771859803, COSV71590484; called by muse, mutect2, varscan2
- MYO18B | c.7153C>T p.R2385W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs767625703, COSV59128196; called by muse, mutect2, varscan2
- NEURL4 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763575063, COSV59761463; called by muse, varscan2
- NT5C1B | c.1228A>G p.T410A (on ENST00000359846 / NM_001199086.2; = p.T350A on NM_033253.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100409783; called by muse, mutect2, varscan2
- OAZ1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763840090, COSV100457244; called by muse, mutect2, varscan2
- PANX2 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1381973443, COSV50292239; called by muse, mutect2, varscan2
- PLA2G6 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as rs757139688, COSV59268365; called by muse, mutect2, varscan2
- PNLDC1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746765267, COSV51704142; called by muse, mutect2, varscan2
- PSG3 | c.585G>T p.L195F | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs750217039, COSV100548675; called by muse, mutect2
- PSMF1 | c.280C>T p.L94= | Splice Region (SNP) | VAF 15/46 reads (33%) | catalogued as rs1253720290, COSV55673245; called by muse, mutect2, varscan2
- PTPN23 | c.3208C>T p.R1070* | Nonsense Mutation (SNP) | VAF 46/175 reads (26%) | catalogued as rs767454205, COSV55543116; called by muse, mutect2, varscan2
- SCML4 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV64634280; called by muse, mutect2, varscan2
- SCP2D1 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV53856733, COSV53857824; called by muse, mutect2, varscan2
- SFTPA2 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV64882645; called by muse, mutect2
- SH3YL1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62155612; called by muse, mutect2, varscan2
- SIN3A | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.217); catalogued as COSV64582115; called by muse, mutect2, varscan2
- SKI | c.1670A>T p.E557V | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66013120; called by muse, mutect2, varscan2
- SNX24 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV54447291; called by muse, mutect2, varscan2
- SYNE1 | c.3896C>T p.A1299V (on ENST00000367255 / NM_182961.4; = p.A1306V on NM_033071.3) | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs1184329555, COSV99553822; called by muse, mutect2, varscan2
- TMEM168 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57179769; called by muse, mutect2, varscan2
- TSHZ2 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 170/240 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs138844500, COSV61592313; called by muse, mutect2, varscan2
- TTYH3 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99349506; called by muse, mutect2, varscan2
- UNC5D | c.2776G>C p.G926R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54776635; called by muse, mutect2, varscan2
- VANGL2 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63604046; called by muse, mutect2, varscan2
- VASN | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as COSV52028612; called by muse, mutect2, varscan2
- VENTX | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs776964051, COSV58084164; called by muse, mutect2, varscan2
- VPS35L | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV51978514; called by muse, mutect2, varscan2
- WDR36 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs558698458, COSV72411058; called by muse, mutect2, varscan2
- ASTN1 | c.2535del p.F845Lfs*64 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- VN1R5 | c.92del p.N31Ifs*6 | Frame Shift Del (DEL) | VAF 118/370 reads (32%) | called by mutect2, pindel, varscan2
- VSTM2A | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- ZDHHC15 | c.974C>A p.P325Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ADAM18 | c.1533A>G p.Q511= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs1488457689, COSV55844930; called by muse, mutect2, varscan2
- ADAMTS16 | c.1770G>A p.S590= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs201912376, COSV56981644; called by muse, mutect2, varscan2
- CARD11 | c.2448C>T p.C816= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as rs748539189, COSV100829142, COSV62754393; called by muse, mutect2, varscan2
- CNPY1 | c.36G>A p.T12= | Silent (SNP) | VAF 73/201 reads (36%) | catalogued as COSV58786553; called by muse, mutect2, varscan2
- FER1L6 | c.1671G>A p.P557= | Silent (SNP) | VAF 108/215 reads (50%) | catalogued as rs371994179, COSV67552002; called by muse, mutect2, varscan2
- HIPK4 | c.579C>T p.C193= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs774119442, COSV52521998; called by muse, mutect2, varscan2
- KIAA0100 | c.1044A>G p.Q348= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as rs773765982, COSV66491124; called by muse, mutect2, varscan2
- LAMA4 | c.5439C>T p.G1813= (on ENST00000230538 / NM_001105206.3; = p.G1806= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs147579862; called by muse, mutect2
- MARCHF8 | c.219G>A p.T73= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs1404316946, COSV60571129; called by muse, mutect2, varscan2
- MTSS1 | c.1560T>C p.P520= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100274420; called by mutect2, varscan2
- NOD2 | c.1650G>A p.L550= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV56048896; called by muse, mutect2, varscan2
- OR10A2 | c.621C>T p.H207= | Silent (SNP) | VAF 140/317 reads (44%) | catalogued as COSV56298886; called by muse, mutect2, varscan2
- PLXNB2 | c.5394G>A p.T1798= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as rs563052435, COSV63780802; called by muse, mutect2, varscan2
- SIN3A | c.960C>T p.G320= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV64582109; called by muse, mutect2, varscan2
- SLC26A9 | c.672C>T p.F224= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs557688842, COSV61601341; called by muse, mutect2, varscan2
- SPTBN5 | c.8739G>A p.L2913= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs770641636, COSV58017644; called by muse, mutect2, varscan2
- SYF2 | c.480T>C p.F160= | Silent (SNP) | VAF 54/76 reads (71%) | catalogued as COSV52573100; called by muse, mutect2, varscan2
- TEX15 | c.3672C>T p.D1224= (on ENST00000256246; = p.D1607= on NM_001350162.2) | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs372369352; called by muse, mutect2, varscan2
- TMEFF2 | c.585C>T p.C195= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs779383447, COSV55829366, COSV55842410; called by muse, mutect2, varscan2
- TUBGCP2 | c.2352C>T p.T784= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs112980465, COSV53303824; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156933 C>T | 3'Flank (SNP) | VAF 43/148 reads (29%) | catalogued as rs997813930; called by muse, mutect2, varscan2
- CFHR1 | c.*2A>G | 3'UTR (SNP) | VAF 65/196 reads (33%) | catalogued as rs1268620556, COSV100258636; called by muse, mutect2
